MMRF case MMRF_1020 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8ed77787-c930-42b7-90e5-4267aa6f9854

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,143 days); ISS stage: I; Days to last known disease status: 1,826 days (5.0 years); Days to last follow up: 1,826 days (5.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 61 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 6 days; Days to treatment end: 91 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 132 days; Days to treatment end: 133 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 135 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 827 days (2.3 years); Days to treatment end: 1,360 days (3.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 987 days (2.7 years); Days to treatment end: 988 days (2.7 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: Second line of therapy; Days to treatment start: 990 days (2.7 years); Days to treatment end: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,370 days (3.8 years); Days to treatment end: 1,623 days (4.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,370 days (3.8 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,638 days (4.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 70.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.235 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.04 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.45 mmol/L; Albumin 47 g/L; Total Protein 7.5 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 92 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.992 mg/dL; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 164 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 1.78 g/L; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 268 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.714 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.8 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.48 ×10⁹/L; Platelets 317 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 350 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 9.67 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 1.38 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.16 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 490 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 9.71 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.09 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 5.45 mmol/L.
- Day 506: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.02 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.08 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 560 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 714 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.641 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 805 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 118 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.233 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 3.23 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 889 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.926 mg/dL; Immunoglobulin G 0.35 g/L; Immunoglobulin A 5.74 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 14.1 ×10⁹/L; Absolute Neutrophil 10.8 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 1,004 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.629 mg/dL; Immunoglobulin G 5.18 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 5.72 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 4.39 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6 mmol/L.
- Day 1,092 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 7.42 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 7.8 g/dL; Glucose 5.06 mmol/L.
- Day 1,148 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 1.17 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.29 mmol/L.
- Day 1,246 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.46 mmol/L.
- Day 1,336 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 44.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 7.1 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 1,428 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.07 mmol/L.
- Day 1,491 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 78.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.96 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.
- Day 1,623 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 94.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.124 mg/dL; Immunoglobulin G 3.27 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.48 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.63 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.
- Day 1,686 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 46.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0253 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 1,826 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0255 mg/dL; Immunoglobulin G 2.04 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.84 ×10⁹/L; Platelets 351 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -14: Weight: 88 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1020_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 805 days (2.2 years).
- Sample MMRF_1020_3_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 805 days (2.2 years).
